TCGA case TCGA-97-8171 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - NYU. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/397d3f69-1453-4057-b177-8723eec923d1

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 81 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C34.8; Tissue or organ of origin: Overlapping lesion of lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 81.1 years (29,627 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T2a; AJCC pathologic N: N2; AJCC pathologic M: M1a; AJCC pathologic stage: Stage IV; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Days to treatment start: 16 days; Treatment outcome: Treatment Ongoing.
2. Metastasis of diagnosis 1 (Papillary adenocarcinoma, NOS). Age at diagnosis: 82.3 years (30,068 days); Days to diagnosis: 441 days (1.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 441 days (1.2 years); Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Days to follow up: 107 days; Disease response: With Tumor.
- Day 441 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Days to progression: 441 days (1.2 years); Evidence of progression type: Biopsy with Histologic Confirmation.
- Days to follow up: 568 days (1.6 years); Disease response: With Tumor.
- ECOG performance status: 1; Timepoint: Preoperative.

Molecular and laboratory tests
- EGFR deletion: Positive; Exon: 19.
- KRAS mutation, nos: Negative.

Other clinical attributes
- DLCO (% of predicted): 110; FEV1/FVC after bronchodilator (%): 55; FEV1/FVC before bronchodilator (%): 55; FEV1 after bronchodilator (% of reference): 104; FEV1 before bronchodilator (% of reference): 99.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 65; Tobacco smoking onset year: 1946.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-97-8171-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.9; Intermediate dimension: 0.8; Shortest dimension: 0.5.
  Slide TCGA-97-8171-01A-01-TS1: Section location: Top; Percent tumor cells: 98; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 0; Percent monocyte infiltration: 2.
- Sample TCGA-97-8171-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-97-8171-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Papillary Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Tobacco smoking history indicator: 2; Anatomic organ subdivision: RUL and RML; KRAS mutation found: No; KRAS gene analysis indicator: Yes; EGFR mutation status: Yes; EGFR mutation identified type: Exon 19 Deletion; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment: Pharmaceutical therapy drug name: Tarceva.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: Yes.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 568 days; disease-specific survival: no event (censored), 568 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 441 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-97-8171-01A-11D-2283-01): tumor purity 0.82, ploidy 2.21, whole-genome doublings 0.
